TCGA case TCGA-58-8392 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Thoraxklinik at University Hospital Heidelberg. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/45aa07c3-cea4-456e-8000-b4572a2163a8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 70 years; Vital status: Dead; Days to death: 501 days (1.4 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 70.4 years (25,710 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 70.7 years (25,806 days); Days to diagnosis: 96 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 96 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 96 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 501 days (1.4 years); Disease response: With Tumor.
- Karnofsky performance status: 70; ECOG performance status: 1; Timepoint: Preoperative.

Molecular and laboratory tests
- EGFR substitution: Positive; Amino-acid change: L858R.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 33; FEV1 before bronchodilator (% of reference): 31.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 80.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-58-8392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-58-8392-01A-01-BS1: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 38; Percent normal cells: 65; Percent necrosis: 2; Percent stromal cells: 3; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 15.
  Slide TCGA-58-8392-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 7; Percent necrosis: 15; Percent stromal cells: 8; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 15.
- Sample TCGA-58-8392-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-58-8392-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-58-8392-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 12; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: Yes; EGFR mutation identified type: L858R; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 501 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 501 days; disease-free interval: event (new tumor event after initially disease-free), 96 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 96 days.
